FM case AD2000 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/278c5a84-347d-4238-8d95-665a2c27598d

Female, 45.7 years: Carcinoma, NOS (ICD-O-3 8010/3); specimen biopsied or resected from the vagina. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
